Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8678, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8678-01A (Primary Tumor).

[page 1 of 3]
[Redacted]

[Redacted] Case ID	[Redacted] ID	Excision date
[Redacted]	[Redacted]	[Redacted] 2

[page 2 of 3]
Gross Description	Microscopic Description	Diagnosis Details

[page 3 of 3]
Comments	Formatted Path Report
	STOMACH TISSUE CHECKLIST Specimen type: Subtotal resection of stomach Tumor site: Fundus Tumor size: 6 x 5 x 4 cm Tumor features: None specified Histologic type: Adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Muscularis propria Lymph nodes: 0/12 positive for metastasis (Regional 0/12) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

Source: NCI Genomic Data Commons file 00eb9d40-a9fa-4b04-a432-9ff89d3c958e (TCGA-BR-8678.240633BB-785E-4B1D-AF6B-9A2FEBCCEF30.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).